Gene-level copy-number profile of tumor specimen TCGA-08-0520-01A from TCGA case TCGA-08-0520, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 70.5 years (25,766 days).
Specimen TCGA-08-0520-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.60048d60-397b-4e0d-af7d-2050551694e8.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 4,946 have no estimate.
https://portal.gdc.cancer.gov/files/8ed84102-0b78-4dfe-ac15-1878214d7c24

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 188; copy number 1: 10,941; copy number 2: 41,080; copy number 3: 3,468.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-08-0520-01): tumor purity 0.81, ploidy 1.88, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 188 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,638,285–22,128,103, 17 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr10:50,990,888–52,298,423, 7 genes (within-gene range 0–1): PRKG1, AL731537.1, AC022537.1, MIR605, AC069079.1, RSU1P3, CSTF2T.
- chr10:53,458,197–53,766,614, 2 genes: RNA5SP318, AL365496.1.
- chr13:91,272,081–102,402,457, 161 genes (within-gene range 0–1) (broad region; genes not listed).
- chr13:102,299,790–102,300,272, 1 gene: AL356266.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 10,941. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
